Somatic mutation profile of tumor specimen C3N-01081-03 (aliquot CPT0211500006) from CPTAC case C3N-01081, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-01081-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b77f36d-94d7-4c8b-8999-fca3d84031ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01081-71 (Blood Derived Normal), aliquot CPT0211600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b10a337-1cdd-49f2-956e-605494633aef

The open-access MAF lists 100 somatic variants for this specimen: 69 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 21, Nonsense Mutation 6, Frame Shift Del 6, Intron 4, Frame Shift Ins 3, RNA 2, 3'UTR 2, 5'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCHE | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 27/102 reads (26%) | catalogued as rs990121358; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 104/408 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.2619dup p.D874Rfs*17 | Frame Shift Ins (INS) | VAF 161/755 reads (21%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- ACVR1 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.403); catalogued as rs1403278698; called by muse, mutect2, varscan2
- ATP1A3 | c.239C>G p.P80R (on ENST00000545399 / NM_001256214.2; = p.P67R on NM_152296.5) | Missense Mutation (SNP) | VAF 207/632 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV57491408; called by muse, mutect2, varscan2
- C1R | c.1526G>A p.R509H (on ENST00000536053 / NM_001354346.2; = p.R495H on NM_001733.7) | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs755913702; called by muse, mutect2, varscan2
- CAPN9 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746333029; called by muse, mutect2, varscan2
- CYTH4 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV50632060; called by muse, mutect2, varscan2
- DHTKD1 | c.661A>C p.M221L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99536110; called by muse, mutect2, varscan2
- FLT4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs780661773, COSV56104523; called by muse, mutect2, varscan2
- GSDMA | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 114/482 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs533792064, COSV56980409; called by muse, mutect2, varscan2
- KCNQ3 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs770863845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527373647, COSV58061898; called by muse, mutect2, varscan2
- MUC5AC | c.14162G>A p.R4721H | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781484473, COSV100611650; called by muse, mutect2, varscan2
- NEBL | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746529858, COSV101009015, COSV65802861; called by muse, mutect2, varscan2
- NFATC4 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs981442583; called by muse, mutect2, varscan2
- NTF3 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100451082, COSV58417857; called by muse, mutect2, varscan2
- PCDHGB2 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53986502; called by muse, mutect2
- PRSS23 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 113/393 reads (29%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.817); catalogued as rs575736317, COSV99722380, COSV99722529; called by muse, mutect2, varscan2
- RFC3 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 103/373 reads (28%) | catalogued as rs1473470348; called by muse, mutect2, varscan2
- SEC63 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765882503; called by muse, mutect2, varscan2
- SPATA1 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as rs749881212; called by muse, mutect2, varscan2
- STXBP1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 141/588 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs1333091651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP35 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs1327839947, COSV71573056; called by muse, mutect2
- WDR81 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1260448488; called by muse, mutect2, varscan2
- ZNF614 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs773266115; called by muse, mutect2, varscan2
- ZNF835 | c.725G>C p.R242P | Missense Mutation (SNP) | VAF 160/621 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73379606, COSV73379622; called by muse, mutect2, varscan2
- ACR | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 151/558 reads (27%) | called by muse, mutect2, varscan2
- AHNAK | c.1265T>A p.V422D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ARHGDIA | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.666C>A p.Y222* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- BAIAP3 | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CHAMP1 | c.2079C>G p.I693M | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYFIP1 | c.1265A>G p.K422R | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DAP3 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DMXL2 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DNAH6 | c.5702A>T p.E1901V | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP8 | c.1498G>C p.A500P (on ENST00000341861 / NM_001320875.2; = p.A484P on NM_017743.6) | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- EFHB | c.835A>C p.T279P | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ERCC6L | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ERMN | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- EXD1 | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2
- GNG7 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- HELZ | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HKDC1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- INSM1 | c.1530C>A p.C510* | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | called by muse, varscan2
- ITIH6 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- KDM6B | c.4594T>A p.L1532M | Missense Mutation (SNP) | VAF 203/455 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- LTN1 | c.1639del p.E547Kfs*22 | Frame Shift Del (DEL) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- MARVELD3 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 152/431 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MICALL1 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | called by muse, varscan2
- MYO10 | c.153C>G p.H51Q | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK3 | c.986_987del p.N329Ifs*3 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.1109dup p.C371Lfs*20 | Frame Shift Ins (INS) | VAF 49/189 reads (26%) | called by mutect2, pindel, varscan2
- NPAS1 | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PNISR | c.1460dup p.N487Kfs*2 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, pindel, varscan2
- PRPH2 | c.360_366del p.L121Gfs*16 | Frame Shift Del (DEL) | VAF 103/428 reads (24%) | called by mutect2, pindel, varscan2
- RAB6C | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCTR | c.1270A>G p.K424E | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SETD2 | c.7514_7515del p.F2505* | Frame Shift Del (DEL) | VAF 93/244 reads (38%) | called by mutect2, pindel, varscan2
- SLC15A5 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SYPL1 | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TENM4 | c.1435del p.Y479Mfs*25 | Frame Shift Del (DEL) | VAF 50/191 reads (26%) | called by mutect2, pindel, varscan2
- TTI2 | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VHL | c.459_463+4del p.X153_splice | Splice Site (DEL) | VAF 73/277 reads (26%) | called by mutect2, pindel, varscan2
- WNK3 | c.1020_1021del p.E340Dfs*10 | Frame Shift Del (DEL) | VAF 31/158 reads (20%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.1787A>C p.E596A | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZFYVE9 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF217 | c.2043T>G p.D681E | Missense Mutation (SNP) | VAF 125/409 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC130 | c.10A>C p.R4= | Silent (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- CPSF6 | c.1002C>T p.P334= | Silent (SNP) | VAF 56/177 reads (32%) | called by muse, mutect2, varscan2
- CRIM1 | c.162C>T p.S54= | Silent (SNP) | VAF 48/534 reads (9%) | called by muse, mutect2
- DISC1 | c.60C>T p.H20= | Silent (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- EDAR | c.1227T>C p.P409= | Silent (SNP) | VAF 168/561 reads (30%) | called by muse, mutect2, varscan2
- EFR3A | c.2010T>C p.G670= | Silent (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- FIGNL2 | c.1650T>C p.S550= | Silent (SNP) | VAF 126/491 reads (26%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1875C>G p.S625= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- GPR37 | c.1755C>T p.N585= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV58255947; called by muse, mutect2, varscan2
- KRTAP20-4 | c.39C>T p.C13= | Silent (SNP) | VAF 27/470 reads (6%) | catalogued as rs550393124, COSV58168186; called by muse, mutect2
- LSP1 | c.969C>T p.T323= | Silent (SNP) | VAF 54/235 reads (23%) | catalogued as rs780994994, COSV61136217; called by muse, mutect2, varscan2
- MCU | c.858C>G p.R286= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as COSV100849090; called by muse, mutect2
- MEPCE | c.855G>A p.P285= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- PLOD1 | c.2142C>G p.T714= | Silent (SNP) | VAF 219/852 reads (26%) | called by muse, mutect2, varscan2
- RPS27A | c.453C>T p.N151= | Silent (SNP) | VAF 105/307 reads (34%) | called by muse, mutect2, varscan2
- SEC16A | c.6726G>A p.G2242= | Silent (SNP) | VAF 35/192 reads (18%) | called by muse, mutect2, varscan2
- SFSWAP | c.2754A>C p.S918= | Silent (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- SLC34A1 | c.1692G>A p.R564= | Silent (SNP) | VAF 44/295 reads (15%) | called by muse, mutect2, varscan2
- SLTM | c.1272A>G p.A424= | Silent (SNP) | VAF 67/261 reads (26%) | called by muse, mutect2, varscan2
- SRRM2 | c.2355C>T p.C785= | Silent (SNP) | VAF 68/334 reads (20%) | called by muse, mutect2, varscan2
- TAF7L | c.802C>T p.L268= | Silent (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840164 C>A | 5'Flank (SNP) | VAF 206/600 reads (34%) | catalogued as rs747725720; called by muse, mutect2, varscan2
- GCNT2 | c.926-35335del | Intron (DEL) | VAF 56/194 reads (29%) | called by mutect2, pindel, varscan2
- LGI3 | chr8:22159722 C>T | 5'Flank (SNP) | VAF 109/319 reads (34%) | called by muse, mutect2, varscan2
- MIR217 | n.92C>T | RNA (SNP) | VAF 43/248 reads (17%) | called by muse, mutect2, varscan2
- MIR217 | n.91G>T | RNA (SNP) | VAF 43/253 reads (17%) | called by muse, mutect2, varscan2
- PDS5B | c.108+17del | Intron (DEL) | VAF 46/203 reads (23%) | called by mutect2, pindel, varscan2
- PKM | c.*135C>A | 3'UTR (SNP) | VAF 113/392 reads (29%) | called by muse, mutect2, varscan2
- RBM33 | c.*48T>A | 3'UTR (SNP) | VAF 134/406 reads (33%) | called by muse, mutect2, varscan2
- SP100 | c.1057+14G>T | Intron (SNP) | VAF 57/208 reads (27%) | catalogued as rs774764875; called by muse, mutect2, varscan2
- TIMP1 | c.329-72G>T | Intron (SNP) | VAF 86/291 reads (30%) | called by muse, mutect2
